Gene-level copy-number profile of tumor specimen HCM-BROD-0960-C16-06A from HCMI case HCM-BROD-0960-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 64.5 years (23,555 days).
Specimen HCM-BROD-0960-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94f6c8d5-d508-4e65-aa87-d71c91988821.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0960-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/614231b2-3e37-4f14-ad69-cc875ff684ed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 393; copy number 2: 3,707; copy number 3: 17,803; copy number 4: 32,265; copy number 5: 3,992; copy number 6: 126; copy number 7: 83; copy number 8: 2; copy number 9: 134; copy number 10: 188; copy number 11: 73; copy number 38: 3; copy number 39: 39; copy number 72: 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,900,238–27,000,886, 7 genes (within-gene range 0–3): NUDC, NR0B2, KDF1, RPL12P13, AL356390.1, OSTCP2, TRNP1.
- chr2:241,227,264–241,354,027, 4 genes: HDLBP, SEPTIN2, AC104841.1, AC005104.1.
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr5:59,039,761–59,314,800, 2 genes (within-gene range 0–4): AC092343.1, AC008833.1.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr7:5,306,790–5,425,414, 3 genes (within-gene range 0–3): TNRC18, AC093620.1, AC092171.1.
- chr7:157,854,529–157,869,154, 2 genes (within-gene range 0–1): PTPRN2-AS1, AC011899.2.
- chr8:85,440,596–85,464,915, 1 gene (within-gene range 0–4): CA3-AS1.
- chr9:14,204,248–14,205,039, 1 gene (within-gene range 0–2): AL441963.1.
- chr10:806,914–931,705, 1 gene: LARP4B.
- chr11:644,233–727,727, 5 genes (within-gene range 0–5): DEAF1, AC131934.1, EPS8L2, TMEM80, AP006621.4.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr11:63,998,558–64,166,113, 5 genes (within-gene range 0–2): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr12:58,872,149–59,064,238, 4 genes: LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr16:2,140,803–2,155,358, 4 genes: RAB26, SNHG19, SNORD60, AC009065.9.
- chr16:19,392,213–19,393,468, 1 gene (within-gene range 0–2): AC130456.7.
- chr16:19,410,729–19,411,662, 1 gene (within-gene range 0–2): AC130456.4.
- chr16:71,833,787–71,931,199, 6 genes (within-gene range 0–4): AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1.
- chr16:88,512,960–88,531,053, 1 gene (within-gene range 0–2): AC116552.1.
- chr17:4,959,226–5,028,401, 11 genes (within-gene range 0–3): SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1.
- chr17:82,614,562–82,698,698, 4 genes (within-gene range 0–3): WDR45B, AC124283.5, RAB40B, MIR4525.
- chr19:1,107,637–1,228,431, 3 genes (within-gene range 0–3): SBNO2, STK11, HMGB2P1.
- chr22:19,969,896–20,016,823, 1 gene (within-gene range 0–2): ARVCF.
- chr22:50,274,979–50,327,012, 4 genes: PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 438 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:34,853,094–38,686,323, 43 genes, copy number 38–72: APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493.
- chr13:73,100,575–73,113,018, 2 genes, copy number 9: FABP5P1, RNU6-66P.
- chr17:8,329,583–20,319,026, 393 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
